Gene-level copy-number profile of tumor specimen C3N-00221-06 (profiled together with C3N-00221-08) from CPTAC case C3N-00221, project CPTAC-3 (Bronchus and lung — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 78.6 years (28,711 days).
Specimen C3N-00221-06: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lung; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file f65af4a7-bcbf-4cc4-8e82-f5ada1b6c506.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-00221-75 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,718 have no estimate.
https://portal.gdc.cancer.gov/files/9d0fb0f5-f08f-4d45-834c-f4cd0fbe6c01

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 168; copy number 1: 1,669; copy number 2: 21,642; copy number 3: 24,431; copy number 4: 6,945; copy number 5: 2,318; copy number 6: 358; copy number 7: 185; copy number 9: 356; copy number 10: 700; copy number 11: 35; copy number 12: 69; copy number 13: 17; copy number 14: 12.

Homozygous deletions (total copy number 0; autosomes only): 168 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:83,937,045–90,261,708, 47 genes: SRRM1P2, LINC00971, AC117482.1, LINC02025, CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P, HSPE1P19.
- chr3:138,652,698–139,006,268, 9 genes (within-gene range 0–1): PIK3CB, GAPDHP39, RPL23AP40, EEF1A1P25, ATP5MC1P3, LINC01391, FOXL2, FOXL2NB, PRR23A.
- chr3:139,019,031–139,020,926, 1 gene (within-gene range 0–1): PRR23B.
- chr4:69,280,475–69,423,164, 7 genes (within-gene range 0–2): UGT2B28, AC114786.3, AC114786.2, AC114786.4, UGT2B25P, AC108078.1, UGT2B24P.
- chr9:12,134–4,587,469, 59 genes (within-gene range 0–1): DDX11L5, WASHC1, MIR1302-9HG, MIR1302-9, FAM138C, AL449043.2, PGM5P3-AS1, AL449043.1, LINC01388, FOXD4, CBWD1, DOCK8-AS1, DOCK8, AL158832.1, AL161725.1, KANK1, RPL12P25, AL161725.2, AL392089.1, RNU6-1327P, EIF1P1, AL136979.1, DMRT1, DMRT3, RNU6-1073P, H3P29, LINC01230, DMRT2, AL356498.1, RPS27AP14, AL358934.1, RNA5SP279, AL591644.1, SMARCA2, AL359076.1, RNU2-25P, RN7SL592P, VLDLR-AS1, AL353614.1, VLDLR, AL450467.1, KCNV2, PUM3, GPS2P1, ATP5PDP2, CARM1P1, LINC01231, RFX3, AL354941.1, RFX3-AS1, AL354977.2, AL354977.1, GLIS3, AL137071.1, GLIS3-AS1, AL359095.1, AL162419.1, RNU6-694P, SLC1A1.
- chr9:5,765,076–6,066,714, 7 genes (within-gene range 0–1): ERMP1, AK4P4, KIAA2026, MLANA, MIR4665, RANBP6, AL162384.1.
- chr9:6,328,375–6,645,729, 7 genes (within-gene range 0–1): TPD52L3, UHRF2, AL133480.1, GLDC, RN7SL25P, AL353718.1, RPL23AP57.
- chr9:7,477,045–7,478,320, 1 gene: RPL4P5.
- chr9:7,914,514–7,961,224, 2 genes: AL135923.2, AL135923.1.
- chr9:9,090,898–9,091,245, 1 gene (within-gene range 0–2): RPS26P3.
- chr9:21,966,929–21,967,751, 1 gene (within-gene range 0–2): CDKN2A-DT.
- chr9:42,231,811–42,950,827, 18 genes (within-gene range 0–2): AL445584.2, FKBP4P6, SDR42E1P2, ATP5F1AP1, RAB28P3, RBPJP6, BX088651.4, BX088651.1, BX088651.2, FGF7P5, BX088651.3, FGF7P4, BX664718.1, BX664718.2, ADGRF5P2, MEP1AP4, ANKRD20A7P, RNU6-599P.
- chr9:64,488,600–64,498,745, 2 genes: GXYLT1P6, AL773524.1.
- chr9:64,817,870–64,889,063, 3 genes (within-gene range 0–2): AL359955.1, AC125634.1, RNU6-1293P.
- chr17:20,481,330–20,494,155, 3 genes: TNPO1P3, YWHAEP3, KRT16P5.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,374 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:146,504,570–198,123,232, 900 genes, copy number 9–10 (broad region; genes not listed).
- chr6:41,267,926–45,664,349, 137 genes, copy number 7–13 (broad region; genes not listed).
- chr6:52,144,349–54,771,134, 71 genes, copy number 7 (broad region; genes not listed).
- chr7:17,299,295–19,002,416, 16 genes, copy number 7 (within-gene range 6–7): AC019117.3, SNORA63, AC019117.2, AC019117.1, AC006482.1, SNX13, AC080080.1, RNMTL1P2, AC080080.2, PRPS1L1, HDAC9, MIR1302-6, AC010082.1, RN7SKP266, HDAC9-AS1, NPM1P13.
- chr17:30,059,052–30,059,147, 2 genes, copy number 9 (within-gene range 4–9): RNY4P13, AC104996.3.
- chr17:30,090,366–34,174,964, 146 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr17:33,692,229–34,156,000, 4 genes, copy number 9 (within-gene range 4–9): AC024614.3, AC024614.4, AC024610.2, AC004147.4.
- chr17:34,155,566–34,165,736, 1 gene, copy number 9 (within-gene range 4–9): AC004147.2.
- chr17:37,375,985–39,864,312, 97 genes, copy number 9–14 (within-gene range 4–14) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 881. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
